Somatic mutation profile of cancer-model specimen HCM-BROD-0478-C16-85M (3D Organoid, passage 7; aliquot HCM-BROD-0478-C16-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0478-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 61.8 years (22,576 days).
Specimen HCM-BROD-0478-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37526420-b482-4042-86ea-15134adafced.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0478-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0478-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b05e7c61-6623-46ad-8feb-e9e944fd7a8f

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Nonsense Mutation 5, Frame Shift Ins 3, Translation Start Site 2, In Frame Ins 2, Intron 1, 3'UTR 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3193G>A p.G1065R | Missense Mutation (SNP) | VAF 128/250 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs587779563, CM1412696, COSV58586859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4280A>G p.Y1427C | Missense Mutation (SNP) | VAF 188/340 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555397548, CM117998; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MUTYH | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 145/275 reads (53%) | catalogued as rs768386527; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 143/143 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADL | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV52055041; called by muse, mutect2, varscan2
- ADAMTS20 | c.3715C>T p.Q1239* | Nonsense Mutation (SNP) | VAF 157/316 reads (50%) | catalogued as COSV67131138; called by muse, mutect2, varscan2
- B4GALT3 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 163/322 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs371112903, COSV100157656; called by muse, mutect2, varscan2
- CCDC175 | c.1895dup p.N632Kfs*6 | Frame Shift Ins (INS) | VAF 40/146 reads (27%) | catalogued as rs1198843594; called by mutect2, varscan2
- CELSR1 | c.4150G>A p.G1384S | Missense Mutation (SNP) | VAF 185/358 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754458990, COSV53085085; called by muse, mutect2, varscan2
- CHMP2A | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs781025283; called by muse, mutect2, varscan2
- CILP2 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 227/492 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.251); catalogued as rs758477493; called by muse, mutect2, varscan2
- COL17A1 | c.3302G>A p.R1101H | Missense Mutation (SNP) | VAF 171/340 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.387); catalogued as rs760623430; called by muse, mutect2, varscan2
- COL18A1 | c.4826G>A p.R1609Q (on ENST00000359759 / NM_130444.3; = p.R1374Q on NM_030582.4) | Missense Mutation (SNP) | VAF 317/644 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); catalogued as rs756649129, COSV60592060; called by muse, mutect2, varscan2
- CSMD1 | c.4628G>A p.R1543Q (on ENST00000520002; = p.R1542Q on NM_033225.6) | Missense Mutation (SNP) | VAF 175/496 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs750382878, COSV59397170; called by muse, mutect2, varscan2
- DCHS1 | c.5132G>A p.R1711Q | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1466443387, COSV55042027; called by muse, mutect2, varscan2
- DNAH5 | c.4703G>A p.R1568H | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs200994058; ClinVar: uncertain significance; called by muse, mutect2
- DOCK9 | c.3607C>T p.P1203S (on ENST00000376460 / NM_001366676.2; = p.P1204S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1461853995; called by muse, mutect2, varscan2
- FREM2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 199/396 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs754308022; called by muse, mutect2, varscan2
- GPRC6A | c.308G>C p.C103S | Missense Mutation (SNP) | VAF 134/259 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59956335; called by muse, mutect2, varscan2
- GSE1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 290/595 reads (49%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.788); catalogued as rs370252559; called by muse, mutect2, varscan2
- HNRNPCL2 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 180/385 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60403000; called by muse, mutect2, varscan2
- HSH2D | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs368588071; called by muse, mutect2, varscan2
- HTR3E | c.1141G>A p.G381S (on ENST00000415389 / NM_001256613.1; = p.G396S on NM_182589.2) | Missense Mutation (SNP) | VAF 139/407 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs184749007, COSV58947434; called by muse, mutect2, varscan2
- INPP5J | c.2711G>A p.R904H (on ENST00000331075 / NM_001284285.2; = p.R536H on NM_001002837.2) | Missense Mutation (SNP) | VAF 249/466 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.373); catalogued as rs774452946; called by muse, mutect2, varscan2
- JUP | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 228/465 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs781804177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC9 | c.3135G>T p.L1045F | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1265837470; called by muse, mutect2, varscan2
- MAGEB3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs140421974, COSV64397165; called by muse, mutect2, varscan2
- MAPK4 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 216/433 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs369990219; called by muse, mutect2, varscan2
- MMP14 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs779735411; called by muse, mutect2, varscan2
- MRGPRF | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 268/405 reads (66%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs559672912; called by muse, mutect2, varscan2
- MYO7A | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 333/487 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782570489; called by muse, mutect2, varscan2
- MYO7A | c.2474G>A p.R825H | Missense Mutation (SNP) | VAF 633/952 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782172320; called by muse, mutect2, varscan2
- NPAS4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 129/446 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs762229451, COSV60650254; called by muse, mutect2, varscan2
- NRXN1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 384/758 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV101281015; called by muse, mutect2, varscan2
- PCDHGA2 | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 145/295 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1183510681, COSV54002582; called by muse, mutect2, varscan2
- PLCB4 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs763071978; called by muse, mutect2, varscan2
- PRELID2 | c.328C>A p.H110N (on ENST00000334744 / NM_182960.4; = p.H69N on NM_138492.6) | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV58280026; called by muse, mutect2, varscan2
- RPL37A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 480/972 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1487469004; called by muse, mutect2, varscan2
- RYR3 | c.6941G>A p.R2314H (on ENST00000389232; = p.R2315H on NM_001036.6) | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109677; called by muse, mutect2, varscan2
- SAMD9 | c.2537G>A p.R846K | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101180285; called by muse, mutect2, varscan2
- SARDH | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 143/299 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751177479; called by muse, mutect2, varscan2
- SPAG17 | c.4343G>A p.R1448Q | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as rs752115449, COSV60452223; called by muse, mutect2, varscan2
- SVEP1 | c.10201G>A p.D3401N | Missense Mutation (SNP) | VAF 127/246 reads (52%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs750101967; called by muse, mutect2, varscan2
- TESK2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs745335345, COSV59148981; called by muse, mutect2, varscan2
- WASF3 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 313/643 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs770387834, COSV58962572; called by muse, mutect2, varscan2
- WDR64 | c.1832G>C p.R611T | Missense Mutation (SNP) | VAF 161/498 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as COSV63797831; called by muse, mutect2, varscan2
- A2M | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP13A3 | c.1424A>T p.K475I | Missense Mutation (SNP) | VAF 495/637 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CEMIP2 | c.2452A>G p.S818G | Missense Mutation (SNP) | VAF 104/199 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTSE | c.880G>A p.G294S (on ENST00000360218; = p.G289S on NM_001910.4) | Missense Mutation (SNP) | VAF 215/447 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA7 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- EQTN | c.639T>A p.Y213* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- FBXO25 | c.1080C>G p.H360Q (on ENST00000382824 / NM_183421.2; = p.H284Q on NM_012173.3) | Missense Mutation (SNP) | VAF 229/633 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FSIP2 | c.2152G>C p.D718H | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA6 | c.698dup p.P234Sfs*66 | Frame Shift Ins (INS) | VAF 216/546 reads (40%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.751del p.S251Afs*10 | Frame Shift Del (DEL) | VAF 22/217 reads (10%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 114/212 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- KIAA1522 | c.1697C>A p.S566Y (on ENST00000373480 / NM_001198972.2; = p.S625Y on NM_020888.3) | Missense Mutation (SNP) | VAF 223/482 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA1522 | c.2001C>G p.D667E (on ENST00000373480 / NM_001198972.2; = p.D726E on NM_020888.3) | Missense Mutation (SNP) | VAF 166/358 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF4A | c.1953G>A p.M651I | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KMT2A | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 240/393 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NCOR1 | c.6061C>T p.Q2021* | Nonsense Mutation (SNP) | VAF 127/127 reads (100%) | called by muse, mutect2, varscan2
- NUTM2D | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 238/1102 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OPN3 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 235/712 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PRDM6 | c.1282A>T p.R428W | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PRDM6 | c.1283G>T p.R428M | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- RASSF7 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 169/394 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- RBM42 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 151/321 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SPAG5 | c.2071dup p.S691Ffs*2 | Frame Shift Ins (INS) | VAF 70/197 reads (36%) | called by mutect2, pindel, varscan2
- TCTE1 | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNRC18 | c.7983_7984insGCC p.S2661_S2662insA | In Frame Ins (INS) | VAF 109/624 reads (17%) | called by pindel, varscan2
- TRPA1 | c.1496A>G p.Q499R | Missense Mutation (SNP) | VAF 119/361 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- WDR26 | c.332_333insCGG p.G125dup (on ENST00000414423 / NM_001379403.1; = p.G25dup on NM_025160.7) | In Frame Ins (INS) | VAF 176/653 reads (27%) | called by pindel, varscan2
- WDR59 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ZNF208 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 123/317 reads (39%) | called by muse, mutect2, varscan2
- ZNF544 | c.994T>G p.C332G | Missense Mutation (SNP) | VAF 170/347 reads (49%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ANKFN1 | c.78C>T p.F26= | Silent (SNP) | VAF 113/225 reads (50%) | catalogued as rs146308617; called by muse, mutect2, varscan2
- EEF2K | c.60A>C p.R20= | Silent (SNP) | VAF 139/288 reads (48%) | called by muse, mutect2, varscan2
- GAN | c.87C>T p.F29= | Silent (SNP) | VAF 293/665 reads (44%) | catalogued as COSV73720751; called by muse, mutect2, varscan2
- HEATR6 | c.2319C>T p.N773= | Silent (SNP) | VAF 128/273 reads (47%) | catalogued as rs780537093, COSV51745637; called by muse, mutect2, varscan2
- IGFN1 | c.948G>A p.A316= | Silent (SNP) | VAF 155/308 reads (50%) | catalogued as rs935217493; called by muse, mutect2, varscan2
- MAP1B | c.2205C>A p.L735= | Silent (SNP) | VAF 144/303 reads (48%) | catalogued as COSV57099382; called by muse, mutect2, varscan2
- MAP3K10 | c.2340G>A p.P780= | Silent (SNP) | VAF 180/350 reads (51%) | called by muse, mutect2, varscan2
- MATN2 | c.126G>A p.P42= | Silent (SNP) | VAF 290/481 reads (60%) | catalogued as rs536601427, COSV54715193; called by muse, mutect2, varscan2
- NCKAP1L | c.1689T>C p.R563= | Silent (SNP) | VAF 116/269 reads (43%) | called by muse, mutect2, varscan2
- NTNG2 | c.639C>T p.F213= | Silent (SNP) | VAF 183/445 reads (41%) | catalogued as rs371305436; called by muse, mutect2, varscan2
- PCDHB14 | c.1329C>T p.D443= | Silent (SNP) | VAF 238/500 reads (48%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2226C>T p.G742= | Silent (SNP) | VAF 234/465 reads (50%) | catalogued as COSV53932366; called by muse, mutect2, varscan2
- SHISAL1 | c.495G>A p.P165= | Silent (SNP) | VAF 232/474 reads (49%) | catalogued as rs781222781; called by muse, varscan2
- SLX4IP | c.1062G>A p.T354= | Silent (SNP) | VAF 135/551 reads (25%) | catalogued as rs372146509; called by muse, mutect2, varscan2
- SORCS2 | c.2214C>T p.D738= | Silent (SNP) | VAF 313/314 reads (100%) | catalogued as rs762656368, COSV100212305; called by muse, mutect2, varscan2
- TRAF7 | c.307C>T p.L103= | Silent (SNP) | VAF 200/427 reads (47%) | called by muse, mutect2, varscan2
- TRPV5 | c.1440C>A p.I480= | Silent (SNP) | VAF 80/273 reads (29%) | called by muse, mutect2, varscan2
- USP40 | c.2163C>T p.S721= | Silent (SNP) | VAF 78/183 reads (43%) | called by muse, mutect2, varscan2
- WNT7A | c.678C>T p.Y226= | Silent (SNP) | VAF 199/569 reads (35%) | catalogued as COSV53197453; called by muse, mutect2, varscan2
- ZNF280B | c.300C>T p.T100= | Silent (SNP) | VAF 189/429 reads (44%) | catalogued as rs894978984; called by muse, mutect2, varscan2
- ZNF407 | c.4998A>T p.S1666= | Silent (SNP) | VAF 164/342 reads (48%) | called by muse, mutect2, varscan2
- ZNRF4 | c.72G>C p.L24= | Silent (SNP) | VAF 220/452 reads (49%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1172G>A | 3'UTR (SNP) | VAF 78/320 reads (24%) | catalogued as rs375110253; called by muse, mutect2, varscan2
- OPRM1 | c.-79G>A | 5'UTR (SNP) | VAF 183/183 reads (100%) | catalogued as rs764289418, COSV100002474; called by muse, mutect2, varscan2
- RER1 | c.366-61G>A | Intron (SNP) | VAF 247/513 reads (48%) | catalogued as rs767391451; called by muse, mutect2, varscan2
